Somatic mutation profile of tumor specimen TCGA-NJ-A4YP-01A (aliquot TCGA-NJ-A4YP-01A-11D-A25L-08) from TCGA case TCGA-NJ-A4YP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.3 years (19,106 days).
Specimen TCGA-NJ-A4YP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad634b03-eab5-48ba-ada3-b984f8a1d187.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NJ-A4YP-10A (Blood Derived Normal), aliquot TCGA-NJ-A4YP-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48083399-d37d-4d57-9036-6fb1f7741f15

The open-access MAF lists 597 somatic variants for this specimen: 436 protein-altering or splice-affecting, 148 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 364, Silent 148, Nonsense Mutation 53, Splice Site 8, Frame Shift Del 7, Intron 3, 3'UTR 3, RNA 3, Splice Region 2, 5'UTR 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.859G>A p.E287K (on ENST00000281708 / NM_001349798.2; = p.E207K on NM_018315.5) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55921895, COSV99662126; called by muse, mutect2, varscan2
- KRAS | c.57G>T p.L19F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs45590836, CM036017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.12544G>C p.E4182Q | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs397516508, COSV100773463; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853992, CM011965, COSV58824824, COSV58824977, COSV58825376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383682; called by muse, mutect2, varscan2
- ABCC11 | c.3399G>T p.Q1133H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100750729, COSV100751273; called by muse, mutect2, varscan2
- ABCC3 | c.3398C>T p.S1133L | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99560106; called by muse, mutect2, varscan2
- ACACB | c.4936C>T p.P1646S | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV58147752; called by muse, mutect2, varscan2
- ACACB | c.4937C>T p.P1646L | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100623432; called by muse, mutect2, varscan2
- ACAD8 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV99844674; called by muse, mutect2, varscan2
- ACE | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs139263584, COSV99328001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM2B | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV100313292; called by muse, mutect2, varscan2
- ACTC1 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99292240; called by muse, mutect2, varscan2
- ACVR1B | c.1383G>C p.Q461H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.035); catalogued as COSV99232285; called by muse, mutect2, varscan2
- ADAMTS10 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99547562; called by muse, mutect2, varscan2
- ADAMTS18 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775375608, COSV99274739; called by muse, mutect2, varscan2
- ADGRA1 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV101658586, COSV101658628; called by muse, mutect2
- AHCTF1 | c.3069G>C p.E1023D (on ENST00000366508; = p.E997D on NM_015446.5) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100404643; called by muse, mutect2, varscan2
- AKAP13 | c.5786C>T p.S1929L (on ENST00000394518 / NM_007200.5; = p.S1933L on NM_006738.6) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774929; called by muse, mutect2, varscan2
- ALDH1L2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99311362; called by muse, mutect2, varscan2
- ANAPC1 | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100595224, COSV61979830; called by muse, mutect2, varscan2
- ANGPTL3 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV99226558; called by muse, mutect2, varscan2
- ANKFY1 | c.2714C>G p.S905C (on ENST00000341657 / NM_001330063.2; = p.S906C on NM_016376.5) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.436); catalogued as COSV100493345, COSV58920438; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3548C>T p.S1183L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99784899; called by muse, mutect2
- ANKRD30A | c.926T>A p.L309* (on ENST00000611781; = p.L253* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100654683; called by muse, mutect2, varscan2
- ANO4 | c.2530G>A p.D844N (on ENST00000392977 / NM_001286615.2; = p.D809N on NM_178826.4) | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100154170; called by muse, mutect2, varscan2
- APAF1 | c.2358C>G p.F786L (on ENST00000551964 / NM_181861.2; = p.F775L on NM_001160.3) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs889240648, COSV100244559, COSV59663745; called by muse, mutect2
- API5 | c.876G>C p.E292D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV101124629; called by muse, mutect2, varscan2
- APOBEC4 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100426204; called by muse, mutect2, varscan2
- APOBR | c.1996G>C p.E666Q (on ENST00000431282; = p.E675Q on NM_018690.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV100113037; called by muse, mutect2
- ARFGAP2 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100125728; called by muse, mutect2, varscan2
- ARHGAP20 | c.2495C>A p.T832K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV99505787; called by muse, mutect2, varscan2
- ARHGAP21 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100256874; called by muse, mutect2, varscan2
- ARID1A | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 10/294 reads (3%) | catalogued as COSV61377237; called by muse, mutect2
- ARID4B | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99936613; called by muse, mutect2, varscan2
- ASPH | c.1398G>C p.L466F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101064630; called by muse, mutect2, varscan2
- ASXL2 | c.2261C>G p.S754C | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.453); catalogued as COSV99712332; called by muse, mutect2, varscan2
- ATG4B | c.1108+3G>A | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99994978; called by muse, mutect2, varscan2
- ATM | c.3973G>C p.E1325Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV99592601; called by muse, mutect2, varscan2
- ATP5F1C | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs765141014, COSV100184437; called by muse, mutect2, varscan2
- ATR | c.6253C>T p.Q2085* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100638734; called by muse, mutect2, varscan2
- ATXN2 | c.3157C>G p.Q1053E (on ENST00000550104; = p.Q893E on NM_002973.4) | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101112934, COSV66485302; called by muse, mutect2, varscan2
- BIRC6 | c.14182G>A p.D4728N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.841); catalogued as COSV101429387; called by muse, mutect2, varscan2
- BLVRA | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.188); catalogued as COSV99646175; called by muse, mutect2, varscan2
- BOD1L1 | c.3796G>T p.A1266S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV50078363; called by muse, mutect2, varscan2
- BPTF | c.3546A>T p.K1182N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100076383; called by muse, mutect2, varscan2
- BTN3A1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99176381; called by muse, mutect2, varscan2
- C1orf127 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV100983511, COSV100983529; called by muse, mutect2, varscan2
- CALR | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100331220; called by muse, mutect2, varscan2
- CAND1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV101598297; called by muse, mutect2
- CAPN6 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV100136810, COSV100136981; called by muse, varscan2
- CASP1 | c.434G>A p.W145* (on ENST00000436863 / NM_033292.4; = p.W124* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100782891; called by muse, mutect2
- CASP10 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53778717, COSV99629459; called by muse, mutect2, varscan2
- CCDC105 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99479936; called by muse, mutect2, varscan2
- CCDC54 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as COSV99660359; called by muse, mutect2, varscan2
- CCDC70 | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as rs755507137, COSV99665459; called by muse, mutect2, varscan2
- CCDC73 | c.2659G>C p.D887H | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068561; called by muse, mutect2, varscan2
- CCDC77 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs1421445279, COSV99520132; called by muse, mutect2
- CCSER1 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.023); catalogued as COSV100397591, COSV61459224; called by muse, mutect2, varscan2
- CCT6A | c.1033G>T p.G345* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99303860; called by muse, mutect2, varscan2
- CD82 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV57036874, COSV99907897; called by muse, mutect2, varscan2
- CD8A | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.337); catalogued as COSV99374665; called by muse, mutect2, varscan2
- CDH11 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1567483357, COSV51760581; called by muse, mutect2, varscan2
- CDH7 | c.441C>G p.N147K | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100543517; called by muse, mutect2, varscan2
- CECR2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV52838360; called by muse, mutect2, varscan2
- CENPB | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs867023076, COSV100713651; called by muse, mutect2, varscan2
- CENPB | c.365G>T p.W122L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100713652; called by muse, mutect2
- CEP192 | c.6636C>G p.I2212M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100382473, COSV58064909; called by muse, mutect2, varscan2
- CEP78 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs373992755; called by muse, mutect2, varscan2
- CFAP77 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100546253; called by muse, mutect2, varscan2
- CGNL1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as COSV99849407; called by muse, mutect2, varscan2
- CHAF1A | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100010880; called by muse, mutect2, varscan2
- CIP2A | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99842749; called by muse, mutect2
- CLCA4 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99760923; called by muse, mutect2, varscan2
- CLRN1 | c.391C>A p.L131M (on ENST00000327047 / NM_174878.3; = p.L55M on NM_052995.2) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV55805322, COSV99902726; called by muse, mutect2, varscan2
- CMKLR1 | c.1093A>G p.M365V (on ENST00000312143 / NM_001142344.2; = p.M363V on NM_004072.3) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370161103; called by muse, mutect2, varscan2
- CMTR2 | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100579408; called by muse, mutect2, varscan2
- CNGB3 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100183396; called by muse, mutect2, varscan2
- COL3A1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as rs780028064, COSV100483981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ8A | c.1807C>G p.P603A | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100507273; called by muse, mutect2
- CPED1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.105); catalogued as COSV100120173, COSV60012177; called by muse, mutect2
- CRAMP1 | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV99246548; called by muse, mutect2, varscan2
- CREB5 | c.394C>T p.Q132* (on ENST00000357727 / NM_182898.4; = p.Q125* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV100745806; called by muse, mutect2, varscan2
- CRISPLD1 | c.850A>T p.I284L | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100082597, COSV51553926; called by muse, mutect2, varscan2
- CRISPLD1 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082598; called by muse, mutect2, varscan2
- CSMD3 | c.2002G>T p.G668C (on ENST00000297405 / NM_001363185.1; = p.G564C on NM_052900.3) | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99852236; called by muse, mutect2, varscan2
- CTSB | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100565986; called by muse, mutect2, varscan2
- CTSC | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV99911055; called by muse, mutect2, varscan2
- CTSS | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100935058; called by muse, mutect2, varscan2
- CTTNBP2 | c.3676A>G p.T1226A | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as rs1369103914, COSV99355185; called by muse, mutect2
- CUL2 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV101039344; called by muse, mutect2, varscan2
- CUL3 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368277; called by muse, mutect2, varscan2
- CUTA | c.340G>T p.E114* (on ENST00000488034 / NM_001014840.2; = p.E91* on NM_015921.3) | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | catalogued as COSV99539291; called by muse, mutect2, varscan2
- DACH1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100499599; called by muse, mutect2, varscan2
- DAOA | c.133+1G>T p.X45_splice | Splice Site (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100298967; called by muse, mutect2, varscan2
- DCLRE1C | c.1610C>T p.S537F (on ENST00000378278 / NM_001350965.2; = p.S422F on NM_022487.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100543249; called by muse, mutect2, varscan2
- DCP1B | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99768052; called by muse, mutect2, varscan2
- DDX50 | c.2112G>C p.Q704H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.205); catalogued as COSV101007338; called by muse, mutect2, varscan2
- DDX59 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV100494766; called by muse, mutect2
- DIDO1 | c.5650G>A p.G1884S | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs897594564; called by muse, mutect2
- DIPK2A | c.960A>T p.Q320H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100237532; called by muse, mutect2, varscan2
- DIRAS3 | c.166A>T p.K56* | Nonsense Mutation (SNP) | VAF 41/151 reads (27%) | catalogued as COSV100921334; called by muse, mutect2, varscan2
- DNAH11 | c.8749G>T p.V2917F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100181557; called by muse, mutect2, varscan2
- DNAH5 | c.1687C>G p.Q563E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs1170897915, COSV54254852; called by muse, mutect2
- DSC2 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV99199982; called by muse, mutect2
- E2F2 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV62276292; called by muse, mutect2
- EEF1B2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV99261656; called by muse, mutect2
- EEF2K | c.1029+1G>A p.X343_splice | Splice Site (SNP) | VAF 34/142 reads (24%) | catalogued as rs1243361839, COSV99533851; called by muse, varscan2
- ELMO1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100163760, COSV100166617; called by muse, mutect2, varscan2
- EPHA7 | c.2628G>T p.E876D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100994509; called by muse, mutect2, varscan2
- ERC1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100706996; called by muse, mutect2, varscan2
- ERG | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101296717, COSV67360624; called by muse, mutect2, varscan2
- ERICH3 | c.1609A>C p.N537H | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100446172; called by muse, mutect2, varscan2
- ERICH6 | c.1866G>T p.W622C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99902139; called by muse, mutect2, varscan2
- ETFB | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99390013; called by muse, mutect2, varscan2
- EXTL2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as rs776971293, COSV100921088, COSV100921155; called by muse, mutect2, varscan2
- F10 | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100979198, COSV100979399; called by muse, mutect2, varscan2
- F13B | c.1331G>T p.W444L | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100803542; called by muse, mutect2, varscan2
- FADD | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV100096787; called by mutect2, varscan2
- FAF2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 7/144 reads (5%) | catalogued as rs1210656384, COSV99990494; called by muse, mutect2
- FAM111B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV100639295, COSV100639383; called by muse, mutect2
- FAM174A | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100444706; called by muse, mutect2, varscan2
- FAM76B | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100716615; called by muse, mutect2, varscan2
- FAR1 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100701687; called by muse, mutect2
- FARSB | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 27/179 reads (15%) | catalogued as COSV99918769; called by muse, mutect2, varscan2
- FAT3 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV99972839; called by mutect2, varscan2
- FAT3 | c.10032C>A p.D3344E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs374591402, COSV99972842; called by muse, mutect2, varscan2
- FBXO38 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV99694166; called by muse, mutect2, varscan2
- FBXO47 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100960917; called by muse, varscan2
- FBXW7 | c.742G>T p.E248* (on ENST00000281708 / NM_001349798.2; = p.E168* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99662131; called by muse, mutect2, varscan2
- FCAR | c.692T>A p.M231K | Missense Mutation (SNP) | VAF 102/508 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100629259; called by muse, mutect2, varscan2
- FCGR3B | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99670836; called by muse, mutect2, varscan2
- FEZ2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100002379; called by muse, mutect2, varscan2
- FGD6 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59698099; called by muse, mutect2, varscan2
- FLNA | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100775433; called by muse, mutect2, varscan2
- FNBP1 | c.1264A>T p.N422Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100852871; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1500G>C p.L500F | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1159085801, COSV100438545; called by muse, mutect2, varscan2
- FREM1 | c.5779C>A p.R1927S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs754692429, COSV101085779; called by muse, mutect2, varscan2
- FREM2 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV54838123; called by muse, mutect2
- FSTL4 | c.2448C>G p.I816M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV54774739, COSV99534176; called by muse, mutect2, varscan2
- FXR1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99976760; called by muse, mutect2, varscan2
- GABRA4 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as COSV99974911; called by muse, mutect2, varscan2
- GBGT1 | c.813G>C p.R271S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100923777, COSV100923804; called by muse, mutect2, varscan2
- GFRA1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816360; called by muse, mutect2, varscan2
- GIT2 | c.1539G>A p.M513I (on ENST00000355312 / NM_057169.5; = p.M465I on NM_014776.5) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100189422; called by muse, mutect2, varscan2
- GMPR2 | c.331G>C p.E111Q (on ENST00000355299 / NM_001351022.2; = p.E129Q on NM_016576.5) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs1486769957, COSV99164685; called by muse, mutect2, varscan2
- GNAQ | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.354); catalogued as COSV99682307; called by muse, mutect2
- GNB5 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1266283712, COSV99953734; called by muse, mutect2, varscan2
- GPR156 | c.998G>T p.S333I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100251817; called by muse, mutect2, varscan2
- GRIK3 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66139388; called by muse, mutect2, varscan2
- GRIK4 | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); catalogued as COSV101483890; called by muse, mutect2, varscan2
- H2AC15 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100357157; called by muse, mutect2, varscan2
- H3C2 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52518035, COSV99451811; called by muse, mutect2, varscan2
- HBG2 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100400743; called by muse, mutect2, varscan2
- HDGFL3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100221000; called by muse, mutect2, varscan2
- HECTD4 | c.11188G>A p.E3730K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.364); catalogued as COSV101107939, COSV66389896; called by muse, mutect2, varscan2
- HEPHL1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100244646; called by muse, mutect2, varscan2
- HERC4 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99517702; called by muse, mutect2, varscan2
- HMCN1 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99637936; called by muse, mutect2, varscan2
- HMCN1 | c.5492C>T p.S1831L | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV54902489; called by muse, mutect2, varscan2
- HTR1D | c.289del p.A97Pfs*62 | Frame Shift Del (DEL) | VAF 38/218 reads (17%) | catalogued as COSV58448220; called by mutect2, pindel, varscan2
- HTR5A | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV55280821, COSV99840092; called by muse, mutect2, varscan2
- IER5L | c.731C>G p.S244W | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100993654; called by muse, mutect2
- IFI16 | c.2234G>A p.G745E (on ENST00000295809 / NM_001364867.2; = p.G689E on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99858377; called by muse, mutect2, varscan2
- IFNA17 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV101303490; called by muse, mutect2
- IFNGR1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV62989414, COSV62990148, COSV62990505; called by muse, mutect2
- IGLV5-52 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1440460343; called by muse, mutect2, varscan2
- IL37 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54490613, COSV99636681; called by muse, mutect2, varscan2
- INTS13 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99677708; called by muse, mutect2, varscan2
- INTS3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 134/610 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100016684; called by muse, mutect2, varscan2
- ITIH4 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.047); catalogued as COSV56577217, COSV99820092; called by muse, mutect2, varscan2
- ITPKC | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs780537334, COSV99649167; called by muse, mutect2, varscan2
- JHY | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.148); catalogued as COSV99913983; called by muse, mutect2, varscan2
- JMJD1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.746); catalogued as COSV101232545; called by muse, mutect2, varscan2
- KAT6A | c.5155G>A p.E1719K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99706126; called by muse, mutect2
- KCNB1 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100870620; called by muse, mutect2, varscan2
- KCNJ8 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV99557782; called by muse, mutect2, varscan2
- KDM4D | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100624409; called by muse, mutect2
- KDM4D | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100624380, COSV100624410; called by muse, mutect2
- KIAA1191 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53800297; called by muse, mutect2, varscan2
- KIF14 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100951144; called by muse, mutect2, varscan2
- KIF16B | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735042, COSV61709400; called by muse, mutect2, varscan2
- KIF24 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100799471; called by muse, mutect2, varscan2
- KIN | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101092738; called by muse, mutect2
- KIR3DL2 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV54396457; called by muse, mutect2, varscan2
- KLB | c.2273G>A p.W758* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV57304576, COSV99962576; called by muse, mutect2, varscan2
- KLHL2 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99900570; called by muse, mutect2, varscan2
- KLHL31 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs759648214, COSV100911876; called by muse, mutect2, varscan2
- KLK11 | c.419G>A p.R140H (on ENST00000594768 / NM_144947.3; = p.R108H on NM_006853.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs200588662; called by muse, mutect2, varscan2
- KNOP1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99575457; called by muse, mutect2, varscan2
- KRT6C | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99360256; called by muse, varscan2
- LAMA3 | c.5914G>T p.E1972* (on ENST00000313654 / NM_198129.4; = p.E363* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99336109; called by muse, mutect2, varscan2
- LAMC1 | c.151A>T p.M51L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV99280717; called by muse, mutect2
- LAMC2 | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99918145; called by muse, mutect2, varscan2
- LARP4 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529815; called by muse, mutect2, varscan2
- LARP4 | c.1928C>A p.S643Y | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV99529817; called by muse, mutect2
- LCE2A | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.117); catalogued as COSV100909229; called by muse, mutect2
- LCK | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV100288297; called by muse, mutect2, varscan2
- LHFPL4 | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV55004642, COSV99805770; called by muse, mutect2, varscan2
- LILRB5 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as rs1385790349, COSV60256356, COSV60260489; called by muse, mutect2, varscan2
- LMAN1L | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59003376; called by muse, mutect2, varscan2
- LTBP1 | c.3402G>T p.Q1134H (on ENST00000404816 / NM_206943.4; = p.Q808H on NM_000627.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99699064; called by mutect2, varscan2
- LUZP2 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100421841; called by muse, mutect2, varscan2
- MAPKAPK3 | c.222C>T p.L74= | Splice Region (SNP) | VAF 50/211 reads (24%) | catalogued as COSV100781802; called by muse, mutect2, varscan2
- MAST2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100788959; called by muse, mutect2, varscan2
- MC3R | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as rs776458621, COSV99710917; called by muse, mutect2, varscan2
- MCM8 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 53/180 reads (29%) | catalogued as COSV99496442; called by muse, mutect2, varscan2
- MGAT4B | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99482492; called by muse, mutect2, varscan2
- MGRN1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV99275091; called by muse, varscan2
- MGRN1 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs767678287, COSV99275096; called by muse, varscan2
- MKNK1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100361596; called by muse, mutect2, varscan2
- MLLT3 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.4); catalogued as COSV100581874; called by muse, mutect2
- MME | c.1094+2T>A p.X365_splice | Splice Site (SNP) | VAF 56/351 reads (16%) | catalogued as COSV100852598; called by muse, mutect2, varscan2
- MMRN1 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99307973; called by muse, mutect2, varscan2
- MS4A14 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.275); catalogued as rs1250077500, COSV100280801; called by muse, mutect2, varscan2
- MS4A4A | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.67); catalogued as rs374427243; called by muse, mutect2, varscan2
- MTCL1 | c.4682C>T p.S1561F (on ENST00000306329 / NM_001378206.1; = p.S1242F on NM_015210.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs200700286, COSV100095988; called by muse, mutect2, varscan2
- MUC16 | c.23575G>A p.A7859T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.197); catalogued as rs763159233, COSV101202329; called by muse, mutect2, varscan2
- MUC4 | c.13654G>A p.E4552K (on ENST00000463781 / NM_018406.7; = p.E316K on NM_004532.6) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV100207035; called by muse, mutect2, varscan2
- MUC5B | c.7733C>T p.T2578I | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1403264932, COSV101500997; called by muse, mutect2, varscan2
- MUC5B | c.8847G>T p.Q2949H | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101500998; called by muse, mutect2, varscan2
- MUSK | c.1754C>A p.A585E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953823198, COSV99079043, COSV99505374; called by muse, mutect2, varscan2
- MYBPC1 | c.995C>T p.S332F (on ENST00000550270 / NM_206820.2; = p.S357F on NM_002465.4) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.974); catalogued as COSV100638350; called by muse, mutect2
- MYH11 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100260595; called by muse, mutect2, varscan2
- MYO9A | c.4676C>T p.S1559F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100614705; called by muse, mutect2, varscan2
- MYOC | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99231797; called by muse, mutect2
- NANOG | c.894G>C p.M298I | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1249767901; called by mutect2, varscan2
- NAPEPLD | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100440155; called by muse, mutect2, varscan2
- NCAM2 | c.2294C>A p.S765* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV53107292; called by muse, mutect2, varscan2
- NCOR1 | c.5969A>T p.Q1990L | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99252926; called by muse, mutect2, varscan2
- NCOR2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV62297568; called by muse, mutect2, varscan2
- NCSTN | c.1937C>G p.S646C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99667784; called by muse, mutect2, varscan2
- NDUFA9 | c.724-1G>T p.X242_splice | Splice Site (SNP) | VAF 26/108 reads (24%) | catalogued as COSV99866259; called by muse, mutect2, varscan2
- NELL1 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV100126137, COSV54335967; called by muse, varscan2
- NEURL1 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); catalogued as COSV100872855; called by muse, mutect2, varscan2
- NF2 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100099880; called by muse, mutect2, varscan2
- NIPA2 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.102); catalogued as rs1355763038, COSV100508978; called by muse, mutect2
- NISCH | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV99234891; called by muse, varscan2
- NLGN3 | c.1593T>G p.F531L (on ENST00000358741 / NM_181303.2; = p.F511L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100705140; called by muse, mutect2
- NLRP12 | c.1377A>T p.R459S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV100146121; called by muse, mutect2, varscan2
- NLRP3 | c.2103G>T p.M701I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100276863; called by muse, mutect2, varscan2
- NMT1 | c.1342G>C p.D448H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365131; called by muse, mutect2, varscan2
- NOD1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs780905084, COSV99768644; called by muse, mutect2, varscan2
- NOS2 | c.1191G>C p.R397S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.941); catalogued as COSV100569972; called by muse, mutect2, varscan2
- NOS3 | c.3581A>T p.D1194V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV99872396; called by muse, mutect2, varscan2
- NOTUM | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101293847; called by muse, mutect2
- NOXO1 | c.208C>T p.L70F (on ENST00000397280 / NM_172168.3; = p.L69F on NM_144603.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1225439140, COSV99937142; called by muse, mutect2, varscan2
- NPM1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV99745053; called by muse, mutect2
- NR1H2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 39/234 reads (17%) | catalogued as COSV99516623; called by muse, mutect2, varscan2
- NR1I3 | c.850G>A p.E284K (on ENST00000367982 / NM_001077480.3; = p.E280K on NM_005122.5) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.048); catalogued as rs768982496, COSV63467410; called by muse, mutect2, varscan2
- NRXN2 | c.3829G>C p.E1277Q | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99636529; called by muse, mutect2, varscan2
- NSD2 | c.3995C>T p.S1332L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs561070783, COSV56389229; called by muse, mutect2, varscan2
- OBSCN | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.688); catalogued as COSV52760137; called by muse, mutect2
- OFD1 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100407238; called by muse, mutect2, varscan2
- OR11H1 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV53272075; called by mutect2, varscan2
- OR1A2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV101126400; called by muse, mutect2, varscan2
- OR1S2 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100224412; called by muse, mutect2, varscan2
- OR5AR1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57252736; called by muse, mutect2
- OR5D13 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100687143, COSV62333035, COSV62335674; called by muse, mutect2, varscan2
- OR5D18 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100450667; called by muse, mutect2, varscan2
- OR5M1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV101591633; called by muse, mutect2
- OR5R1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 15/96 reads (16%) | catalogued as COSV56573527; called by muse, mutect2, varscan2
- OR6A2 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187878752, COSV100215857; called by muse, mutect2, varscan2
- OVCH1 | c.1049C>A p.S350* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100549402, COSV58964133; called by muse, mutect2, varscan2
- P2RX7 | c.882-1G>C p.X294_splice | Splice Site (SNP) | VAF 9/84 reads (11%) | catalogued as COSV55856888, COSV99947852; called by muse, mutect2, varscan2
- PARD3 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301951039, COSV100402339; called by muse, mutect2, varscan2
- PCDHA3 | c.1010T>A p.L337Q | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.916); catalogued as COSV100793869; called by muse, mutect2, varscan2
- PCDHB2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); catalogued as COSV99167242; called by muse, mutect2, varscan2
- PCDHGA10 | c.1655T>A p.L552* | Nonsense Mutation (SNP) | VAF 61/277 reads (22%) | catalogued as COSV99549961; called by muse, mutect2, varscan2
- PCDHGA12 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV99343168; called by muse, mutect2, varscan2
- PCDHGA8 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99532496, COSV99549960; called by muse, mutect2, varscan2
- PEAK1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100433267, COSV100433603; called by muse, mutect2, varscan2
- PHACTR1 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as COSV100279335, COSV60682279; called by muse, mutect2, varscan2
- PIGQ | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99216687; called by muse, mutect2
- PJA2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100754593; called by muse, mutect2, varscan2
- PJA2 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs758566292, COSV100754304; called by muse, mutect2, varscan2
- PKNOX1 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as COSV52338499; called by muse, mutect2
- PLAT | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99535541; called by mutect2, varscan2
- PLCB4 | c.2296G>C p.D766H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99597349; called by muse, mutect2
- PLPPR4 | c.1442C>A p.S481* | Nonsense Mutation (SNP) | VAF 33/161 reads (20%) | catalogued as COSV100926984; called by muse, mutect2, varscan2
- PLXND1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs747172721, COSV60717160; called by muse, mutect2, varscan2
- PNPLA7 | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV53007256, COSV99481799; called by muse, mutect2, varscan2
- POLA2 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.655); catalogued as COSV99641557; called by muse, mutect2, varscan2
- POLG | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM041067, COSV99175154; called by muse, mutect2, varscan2
- POLR2B | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV100108447; called by muse, mutect2
- POM121L12 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.192); catalogued as rs199630026, COSV101375011, COSV68693079; called by muse, mutect2, varscan2
- POTEF | c.3228G>T p.*1076Yext*73 | Nonstop Mutation (SNP) | VAF 67/234 reads (29%) | catalogued as COSV100665495; called by muse, mutect2, varscan2
- PPDPF | c.233C>G p.S78W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs759954043, COSV100925652; called by muse, mutect2, varscan2
- PPEF2 | c.1644G>T p.R548S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99714664; called by muse, mutect2, varscan2
- PPP1CB | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV99942030; called by muse, mutect2
- PPP3CA | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as COSV100547878, COSV100548159; called by muse, mutect2, varscan2
- PRAG1 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100423012; called by muse, mutect2, varscan2
- PRDX6 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100458612; called by muse, mutect2, varscan2
- PRKCZ | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66067425; called by muse, mutect2
- PRPSAP2 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV99264803; called by muse, mutect2, varscan2
- PRRG4 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as rs778682926, COSV99141446; called by muse, mutect2, varscan2
- PSMD13 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100728981, COSV61500304; called by muse, mutect2, varscan2
- PTPMT1 | c.509A>T p.H170L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100442993; called by muse, mutect2, varscan2
- PTPN22 | c.1303G>T p.G435* (on ENST00000359785 / NM_001193431.2; = p.G380* on NM_012411.5) | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100704067; called by muse, mutect2, varscan2
- PTTG1 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV100750966; called by muse, varscan2
- PYHIN1 | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV100932438; called by muse, mutect2, varscan2
- QTRT1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.059); catalogued as COSV99139222; called by muse, mutect2, varscan2
- RAB25 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100737444; called by muse, mutect2, varscan2
- RBFOX1 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100304150; called by muse, varscan2
- RBM25 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV99999243; called by muse, mutect2, varscan2
- RBM43 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100508703; called by muse, mutect2, varscan2
- RFPL1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100585942; called by muse, mutect2, varscan2
- RGS2 | c.20del p.L7Wfs*27 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as COSV99343478; called by pindel, varscan2
- RIF1 | c.4151C>A p.S1384Y | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs775053939, COSV99691501; called by muse, mutect2, varscan2
- RNF133 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57373944; called by muse, mutect2, varscan2
- RNF151 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.239); catalogued as rs760351448, COSV100364565; called by muse, mutect2
- RNF167 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs749500216, COSV99337675; called by muse, varscan2
- ROBO3 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as COSV101185252, COSV67300966; called by muse, mutect2, varscan2
- RP1L1 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV101223815; called by muse, varscan2
- RPTN | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs766765141, COSV100285922, COSV60166408; called by muse, mutect2, varscan2
- RRP36 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773848628, COSV55064057, COSV55064727; called by muse, mutect2, varscan2
- RTN1 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99957253; called by muse, mutect2, varscan2
- RWDD2B | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99725742; called by muse, mutect2
- RYR1 | c.4656C>A p.F1552L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401779403, COSV100616091, COSV100617396; called by muse, mutect2, varscan2
- RYR1 | c.5050C>G p.L1684V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100617397; called by muse, mutect2, varscan2
- RYR2 | c.7274C>T p.S2425F | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100767278; called by muse, mutect2, varscan2
- SACS | c.4147C>G p.H1383D | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101207868; called by muse, mutect2, varscan2
- SCN11A | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.197); catalogued as COSV100182980; called by muse, mutect2, varscan2
- SDK1 | c.3940-1G>T p.X1314_splice | Splice Site (SNP) | VAF 15/83 reads (18%) | catalogued as rs1156403359, COSV101270058; called by muse, mutect2, varscan2
- SGCB | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV101197763; called by muse, mutect2, varscan2
- SGCD | c.446T>C p.F149S (on ENST00000435422 / NM_001128209.2; = p.F150S on NM_000337.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100551489; called by muse, mutect2, varscan2
- SHANK3 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV53188073, COSV99438306; called by muse, mutect2
- SIGLEC1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs770582882, COSV52458858; called by muse, mutect2, varscan2
- SLC17A6 | c.1580A>T p.E527V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV99582639; called by muse, mutect2, varscan2
- SLC26A7 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99404664; called by muse, mutect2, varscan2
- SLC30A9 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100048610; called by muse, mutect2, varscan2
- SLC39A12 | c.1731C>G p.I577M (on ENST00000377369 / NM_001145195.2; = p.I540M on NM_152725.3) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101070227, COSV66197286; called by muse, mutect2
- SLC7A13 | c.240A>C p.Q80H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV99879350; called by muse, mutect2, varscan2
- SMIM29 | c.154G>C p.E52Q (on ENST00000394990 / NM_001008704.3; = p.E72Q on NM_178508.5) | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100102799; called by muse, mutect2, varscan2
- SNX10 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100640152; called by muse, mutect2
- SP100 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV50975758, COSV99894573; called by muse, mutect2, varscan2
- SP140 | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV100614195, COSV59454691; called by muse, mutect2, varscan2
- SPATA21 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as rs773955939, COSV100131494; called by muse, mutect2, varscan2
- SPHKAP | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV60882461; called by muse, mutect2
- SPTA1 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759643; called by muse, mutect2, varscan2
- SRCAP | c.6877G>T p.E2293* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99351820; called by muse, mutect2, varscan2
- STAC2 | c.981G>C p.E327D | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100336550; called by muse, mutect2, varscan2
- STK3 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101372697; called by muse, mutect2, varscan2
- STYXL1 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1024506897, COSV99951725; called by muse, mutect2, varscan2
- STYXL1 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99951726; called by muse, mutect2, varscan2
- SYT16 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374283682, COSV101413525; called by muse, mutect2
- TCERG1 | c.2700C>G p.I900M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV99695419; called by muse, mutect2, varscan2
- TCTA | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55534385, COSV99648811; called by muse, mutect2, varscan2
- TDRD7 | c.840G>T p.W280C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795821; called by muse, mutect2, varscan2
- TECPR1 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101130838; called by muse, mutect2, varscan2
- TECPR2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100850266; called by muse, mutect2, varscan2
- TENM3 | c.1474C>A p.H492N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101305568; called by muse, mutect2, varscan2
- TESK1 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV99427706; called by muse, varscan2
- TESK1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99427708; called by muse, varscan2
- TEX15 | c.3026G>A p.R1009K (on ENST00000256246; = p.R1392K on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV56356247; called by muse, mutect2
- TG | c.3889C>T p.Q1297* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as rs756225459, COSV99604077; called by muse, mutect2, varscan2
- THAP6 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV100293189; called by muse, mutect2, varscan2
- TIAM1 | c.1820G>T p.W607L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV99740012; called by muse, mutect2, varscan2
- TLE1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 41/184 reads (22%) | catalogued as COSV100916039; called by muse, mutect2, varscan2
- TMEFF1 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV100614379; called by muse, mutect2, varscan2
- TMEM177 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99733770; called by muse, mutect2, varscan2
- TMEM196 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV101337537, COSV68255396; called by muse, mutect2
- TNRC6A | c.3594A>C p.E1198D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100170665; called by muse, mutect2, varscan2
- TNS4 | c.1436A>T p.Y479F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV99564260; called by muse, mutect2, varscan2
- TNXB | c.6812G>C p.G2271A (on ENST00000647633; = p.G2024A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.97); catalogued as COSV64476229; called by muse, mutect2, varscan2
- TPTE | c.686G>A p.R229Q (on ENST00000618007 / NM_199261.4; = p.R211Q on NM_199259.4) | Missense Mutation (SNP) | VAF 61/616 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs566493792; called by muse, mutect2
- TRDMT1 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs371526424, COSV100004206; called by muse, mutect2, varscan2
- TRIM13 | c.621G>C p.M207I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100078627, COSV53951265; called by muse, mutect2, varscan2
- TRIM13 | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV100078630, COSV53949248; called by muse, mutect2, varscan2
- TRMT10C | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1559949550, COSV99998428; called by muse, mutect2, varscan2
- TRPC4 | c.2231C>T p.S744F (on ENST00000379705 / NM_016179.4; = p.S749F on NM_003306.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1392188955, COSV100158382; called by muse, mutect2, varscan2
- TRPM6 | c.3439C>T p.H1147Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV100667181; called by muse, mutect2, varscan2
- TRPM8 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100224781, COSV61223487; called by muse, mutect2
- TTN | c.44744G>A p.G14915E (on ENST00000591111; = p.G7491E on NM_003319.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | PolyPhen probably damaging (1); catalogued as rs866384387, COSV60012244, COSV60238614; called by mutect2, varscan2
- TTN | c.13799T>C p.V4600A (on ENST00000591111; = p.V3673A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | PolyPhen probably damaging (0.99); catalogued as COSV100636289; called by muse, mutect2, varscan2
- UBQLNL | c.1094C>A p.T365N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV100975785; called by muse, mutect2, varscan2
- UGT2A1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99685107; called by muse, mutect2, varscan2
- UGT2A1 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99685111; called by muse, mutect2, varscan2
- UNC93B1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57097599, COSV57100172, COSV57100967; called by muse, mutect2, varscan2
- USH2A | c.14954G>C p.R4985T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100244593; called by muse, mutect2, varscan2
- USH2A | c.7107C>G p.F2369L | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100244596, COSV56446080; called by muse, mutect2
- VANGL2 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 89/151 reads (59%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.585); catalogued as COSV100925629, COSV63604032; called by muse, mutect2, varscan2
- VCAN | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs778351592, COSV99427906; called by muse, mutect2, varscan2
- VCAN | c.9279C>A p.C3093* | Nonsense Mutation (SNP) | VAF 47/266 reads (18%) | catalogued as COSV99427908; called by muse, mutect2, varscan2
- VIT | c.1648G>A p.D550N (on ENST00000389975 / NM_001177969.1; = p.D565N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.772); catalogued as rs757456741, COSV99061749; called by muse, mutect2, varscan2
- WDR47 | c.1994A>C p.Y665S (on ENST00000369962 / NM_001142551.2; = p.Y666S on NM_014969.5) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100728507, COSV63060002; called by muse, mutect2, varscan2
- WDR88 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100866670; called by muse, mutect2, varscan2
- WDR91 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100615894; called by muse, mutect2, varscan2
- WEE1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV100219863; called by muse, mutect2, varscan2
- WNT8A | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100843124; called by muse, mutect2, varscan2
- WSB1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 49/227 reads (22%) | catalogued as COSV99286247; called by muse, mutect2, varscan2
- XKR8 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100874626; called by muse, mutect2
- YARS2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV61402213, COSV61402395; called by muse, mutect2, varscan2
- YEATS2 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100528443; called by muse, mutect2
- YWHAH | c.88-2A>C p.X30_splice | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99963871; called by muse, varscan2
- Z84488.1 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious, low confidence (0.02); catalogued as COSV100889428, COSV100889482; called by muse, varscan2
- ZHX1 | c.2166G>C p.W722C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99933970; called by muse, mutect2, varscan2
- ZNF107 | c.20-2A>T p.X7_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100788590; called by muse, mutect2, varscan2
- ZNF232 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100005859; called by muse, varscan2
- ZNF239 | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV100021966; called by muse, mutect2, varscan2
- ZNF267 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100339990; called by muse, mutect2, varscan2
- ZNF304 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV99988946; called by muse, mutect2, varscan2
- ZNF318 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100546609; called by muse, mutect2, varscan2
- ZNF318 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100049936; called by muse, mutect2, varscan2
- ZNF341 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100678198; called by muse, mutect2
- ZNF45 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99524303; called by muse, mutect2
- ZNF451 | c.2962G>C p.E988Q (on ENST00000370706 / NM_001031623.3; = p.E940Q on NM_015555.2) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as COSV100675198; called by muse, mutect2, varscan2
- ZNF501 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs564544043, COSV101247175; called by muse, mutect2, varscan2
- ZNF540 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV100329985; called by muse, mutect2, varscan2
- ZNF570 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100356332; called by muse, mutect2, varscan2
- ZNF605 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV100053589; called by muse, mutect2, varscan2
- ZNF628 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52702701, COSV99220390; called by muse, mutect2, varscan2
- ZNF644 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV100494816; called by muse, mutect2, varscan2
- ZNF680 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100549382; called by muse, mutect2
- ZNF680 | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100549383; called by muse, mutect2
- ZNF800 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 52/198 reads (26%) | catalogued as COSV99758312; called by muse, mutect2, varscan2
- ZRANB2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV54671872; called by muse, mutect2
- ZSWIM8 | c.3887C>G p.S1296C (on ENST00000605216 / NM_001242487.2; = p.S1301C on NM_015037.3) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100014456; called by muse, mutect2
- ZZEF1 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV101068263; called by muse, mutect2
- ABHD12B | c.414del p.N139Tfs*20 (on ENST00000337334 / NM_001206673.2; = p.N62Tfs*20 on NM_181533.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 65/173 reads (38%) | called by mutect2, pindel, varscan2
- FAM229B | c.75del p.L27* | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- GABRA2 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GABRR3 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GNPAT | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- NR4A2 | c.594del p.H199Tfs*4 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- OR11L1 | c.636dup p.L213Sfs*57 | Frame Shift Ins (INS) | VAF 22/139 reads (16%) | called by mutect2, varscan2
- PCDHGB2 | c.2199del p.K734Sfs*35 | Frame Shift Del (DEL) | VAF 37/195 reads (19%) | called by mutect2, pindel, varscan2
- PEG10 | c.907C>A p.H303N (on ENST00000482108 / NM_001040152.2; = p.H337N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- PMEPA1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- POLR2A | c.2477C>G p.S826C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RIPOR2 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.641); called by muse, mutect2
- TUBB | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); called by muse, mutect2
- TUBB4A | c.1199del p.G400Afs*16 | Frame Shift Del (DEL) | VAF 59/287 reads (21%) | called by mutect2, pindel, varscan2
- VCX | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ZZEF1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- A1CF | c.69G>C p.L23= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs759270416, COSV99255794, COSV99258449; called by muse, mutect2, varscan2
- AARS1 | c.1158C>G p.L386= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV55747053, COSV99933903; called by muse, mutect2, varscan2
- AARS1 | c.1017C>T p.L339= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV99933904; called by muse, mutect2, varscan2
- ABCA7 | c.5476C>T p.L1826= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99566875; called by muse, mutect2, varscan2
- ACTR5 | c.1038G>A p.L346= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as rs1376950780, COSV99710342; called by muse, mutect2, varscan2
- ADCY8 | c.2079G>T p.L693= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV99655078; called by muse, mutect2, varscan2
- ADGRF1 | c.1335C>T p.Y445= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV99347781; called by muse, mutect2
- AGPAT4 | c.540C>T p.F180= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100212312; called by muse, mutect2
- APAF1 | c.1026C>G p.L342= (on ENST00000551964 / NM_181861.2; = p.L331= on NM_001160.3) | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as rs961947459, COSV100244557; called by muse, mutect2, varscan2
- ARHGAP31 | c.4194C>T p.V1398= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99957985; called by muse, mutect2
- ARMCX1 | c.1236C>T p.F412= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV100863170, COSV65705296; called by muse, mutect2, varscan2
- ASXL3 | c.4737T>C p.F1579= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99327202; called by muse, mutect2, varscan2
- ATP11B | c.2397G>A p.Q799= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100018275, COSV60028353; called by muse, mutect2
- C16orf86 | c.744C>T p.L248= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs765186036, COSV99708373; called by muse, mutect2, varscan2
- CACNA2D4 | c.1989G>A p.G663= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1301926830, COSV54962016; called by muse, mutect2, varscan2
- CALCR | c.36G>T p.L12= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV100810922; called by muse, mutect2, varscan2
- CALHM6 | c.613C>T p.L205= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs374715644; called by muse, varscan2
- CBWD1 | c.603C>G p.L201= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV100071413; called by muse, mutect2
- CDC73 | c.1453C>T p.L485= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs761968225, COSV100814086; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK15 | c.255G>A p.L85= (on ENST00000652192 / NM_001366386.2; = p.L34= on NM_139158.2) | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99643882; called by muse, mutect2, varscan2
- CELSR1 | c.3786C>T p.F1262= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99420649; called by muse, mutect2, varscan2
- CLCN1 | c.930G>T p.T310= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV100578714, COSV58371259; called by muse, mutect2, varscan2
- CMTR1 | c.1389G>A p.V463= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV100990974; called by muse, mutect2, varscan2
- CNBD2 | c.684G>A p.Q228= | Silent (SNP) | VAF 60/251 reads (24%) | catalogued as COSV100839206; called by muse, mutect2, varscan2
- CUX2 | c.1977G>A p.K659= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1460692197, COSV99921138; called by muse, varscan2
- CXCL3 | c.323G>A p.*108= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs547742552, COSV99932843; called by muse, mutect2, varscan2
- DDX60 | c.1257C>G p.V419= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV67095330; called by muse, mutect2, varscan2
- DGKB | c.267C>T p.N89= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99344608; called by muse, mutect2, varscan2
- DNAH9 | c.11679G>C p.S3893= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1233G>A p.L411= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99972038; called by muse, mutect2
- DOP1A | c.3393G>A p.V1131= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99383226; called by muse, mutect2, varscan2
- ELAVL2 | c.30T>A p.T10= | Silent (SNP) | VAF 63/312 reads (20%) | catalogued as COSV99807555; called by muse, mutect2, varscan2
- ELF2 | c.1083C>T p.I361= (on ENST00000379550 / NM_001331036.2; = p.I301= on NM_006874.4) | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99643418; called by muse, mutect2, varscan2
- ELP1 | c.2694T>C p.Y898= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV101010559; called by muse, mutect2, varscan2
- ELP6 | c.591G>A p.L197= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV99948263; called by muse, mutect2, varscan2
- EPHA1 | c.885C>T p.L295= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1485301693, COSV99315014; called by muse, mutect2, varscan2
- ERN2 | c.1464G>T p.R488= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV99892746; called by muse, mutect2, varscan2
- FADD | c.60G>A p.L20= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100096786; called by muse, mutect2
- FANCD2OS | c.480C>T p.L160= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99812896; called by muse, mutect2, varscan2
- FBXO10 | c.2556C>T p.I852= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs772130360, COSV99447439; called by muse, mutect2, varscan2
- FKBP6 | c.753G>A p.K251= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- FMO1 | c.738C>T p.S246= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100707703, COSV100708023; called by muse, mutect2, varscan2
- GABRA2 | c.207C>T p.F69= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100734871; called by muse, mutect2, varscan2
- GALNT5 | c.345G>A p.Q115= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV99375695; called by muse, mutect2
- GAP43 | c.183T>A p.A61= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100526073; called by muse, mutect2, varscan2
- GBP6 | c.1626G>C p.L542= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100969750; called by muse, mutect2, varscan2
- GLRX3 | c.399C>G p.L133= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs1298722028, COSV100488025; called by muse, mutect2
- GRIN1 | c.2673C>T p.F891= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV100160873; called by muse, mutect2, varscan2
- GRIN3A | c.708T>A p.L236= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV100701971; called by muse, mutect2, varscan2
- GRK6 | c.1458C>T p.V486= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV62681920; called by muse, mutect2
- GSDMA | c.636C>T p.V212= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100053863; called by muse, mutect2, varscan2
- GUF1 | c.348C>T p.I116= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99877548; called by muse, mutect2, varscan2
- HCK | c.786C>T p.L262= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99394773; called by muse, mutect2
- HCN1 | c.2454C>G p.P818= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100302981, COSV57509344; called by muse, mutect2, varscan2
- HDGF | c.21G>A p.Q7= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100625957; called by muse, mutect2, varscan2
- HECTD4 | c.11187G>A p.L3729= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV101108448; called by muse, mutect2, varscan2
- HES4 | c.246G>A p.E82= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs774500086, COSV100515208; called by muse, mutect2, varscan2
- HIF1AN | c.564C>A p.L188= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100142907; called by muse, mutect2, varscan2
- HIPK3 | c.3558C>T p.I1186= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV100306158, COSV57566356; called by muse, mutect2, varscan2
- HK1 | c.2727G>T p.V909= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100068266, COSV53861863; called by muse, mutect2, varscan2
- HTRA4 | c.1164C>T p.L388= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV100206054; called by muse, mutect2, varscan2
- IL17F | c.123C>T p.F41= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100277332; called by muse, mutect2, varscan2
- IL31RA | c.381C>T p.T127= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs777290625, COSV99763742; called by muse, mutect2, varscan2
- IPO7 | c.351C>T p.I117= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV101121860; called by muse, mutect2, varscan2
- KCNH1 | c.1821C>G p.L607= (on ENST00000271751 / NM_172362.3; = p.L580= on NM_002238.4) | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV55082515, COSV99662160; called by muse, mutect2, varscan2
- KIAA0319 | c.585C>T p.F195= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100985881; called by muse, mutect2, varscan2
- KIFC1 | c.1149A>G p.G383= | Silent (SNP) | VAF 64/202 reads (32%) | catalogued as COSV100997151; called by muse, mutect2, varscan2
- KIRREL2 | c.81G>T p.L27= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV99384584; called by muse, mutect2, varscan2
- KRT84 | c.852C>T p.L284= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs762790833, COSV57770922; called by muse, mutect2, varscan2
- LMNB2 | c.372G>A p.L124= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100322075, COSV100322531; called by muse, mutect2, varscan2
- LRRTM4 | c.1152C>T p.I384= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs34870411, COSV69139533, COSV69139821; called by muse, mutect2, varscan2
- LY75 | c.900C>T p.L300= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV99717208; called by muse, mutect2, varscan2
- MAPT | c.2370G>A p.V790= (on ENST00000262410 / NM_001377265.1; = p.V398= on NM_005910.5) | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV99291607; called by muse, mutect2, varscan2
- MCTP1 | c.2682C>T p.I894= | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as COSV100388489; called by muse, varscan2
- MEOX1 | c.573C>A p.A191= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100233660, COSV100233846; called by muse, mutect2
- MISP | c.57C>T p.T19= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs375896627; called by muse, mutect2, varscan2
- MTA1 | c.1413C>T p.F471= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs782127450, COSV100495581; called by muse, mutect2, varscan2
- MTARC2 | c.423C>G p.S141= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as COSV100831114; called by muse, mutect2, varscan2
- MTHFD1L | c.2229G>T p.T743= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV66224098; called by muse, mutect2, varscan2
- MUC16 | c.42387C>A p.I14129= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101110138, COSV66689861; called by muse, mutect2
- MVK | c.837G>A p.L279= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs374187676; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1D | c.2925G>A p.K975= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100532184; called by muse, mutect2
- MYO7B | c.6003C>T p.I2001= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100265132; called by muse, mutect2
- NCAM2 | c.2196G>A p.L732= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs922696384, COSV99521772; called by muse, mutect2, varscan2
- NLRP4 | c.795G>A p.L265= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100017473; called by muse, mutect2
- NLRP9 | c.2745G>A p.L915= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV100243702; called by muse, mutect2
- NPAP1 | c.1983C>A p.L661= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV100276416; called by muse, mutect2, varscan2
- NRDE2 | c.921C>T p.L307= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV62963089; called by muse, mutect2, varscan2
- NUP98 | c.3708C>G p.L1236= (on ENST00000359171 / NM_001365126.1; = p.L1219= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100263773; called by muse, mutect2, varscan2
- OR4D1 | c.213C>G p.L71= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as COSV99274369; called by muse, mutect2, varscan2
- OR6N2 | c.660G>A p.R220= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100210512, COSV100210578; called by muse, mutect2, varscan2
- PABPC1L | c.1176G>A p.L392= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV99408287; called by muse, mutect2
- PCDH18 | c.1365C>T p.I455= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as COSV100787148, COSV100787585; called by muse, mutect2, varscan2
- PCF11 | c.174C>T p.I58= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100019487; called by muse, mutect2, varscan2
- PCYT1A | c.180C>T p.V60= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99492530; called by muse, mutect2, varscan2
- PHLDB3 | c.732G>A p.E244= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99416191; called by muse, mutect2, varscan2
- PIGG | c.693G>A p.L231= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV56321142; called by muse, mutect2, varscan2
- PKLR | c.1635C>T p.F545= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100713103; called by muse, mutect2
- PNPLA3 | c.930G>T p.L310= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99337426; called by muse, mutect2, varscan2
- PPFIA1 | c.966C>T p.I322= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV99558221; called by muse, mutect2, varscan2
- PPP1R3A | c.651A>G p.T217= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV99494866; called by muse, mutect2, varscan2
- PRRC2C | c.7317G>A p.L2439= (on ENST00000367742; = p.L2437= on NM_015172.4) | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100146345, COSV58902546; called by muse, mutect2, varscan2
- PRSS1 | c.411G>A p.T137= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs369013081, COSV61190980; called by muse, mutect2, varscan2
- RAVER2 | c.717C>T p.P239= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as COSV99605810; called by muse, mutect2, varscan2
- RBFOX1 | c.861G>T p.A287= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100304144; called by muse, varscan2
- RBM12B | c.2529C>T p.F843= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs749792658, COSV101234591; called by muse, mutect2
- RELN | c.5619C>A p.T1873= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV59009625; called by muse, mutect2, varscan2
- RGP1 | c.921C>T p.L307= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV65240719; called by muse, mutect2, varscan2
- RINT1 | c.672C>G p.L224= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99994701; called by muse, mutect2
- RNF40 | c.1308G>T p.G436= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1158918153, COSV100222439; called by muse, mutect2, varscan2
- ROGDI | c.597C>A p.L199= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100434220, COSV59020892; called by muse, mutect2, varscan2
- RP1L1 | c.1794C>A p.T598= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV101223817; called by muse, mutect2
- RYR3 | c.5373C>G p.V1791= | Silent (SNP) | VAF 61/259 reads (24%) | catalogued as COSV101215304; called by muse, mutect2, varscan2
- SBF1 | c.456C>T p.I152= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100818158; called by muse, mutect2
- SCN4A | c.708G>A p.L236= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV101438722; called by muse, mutect2, varscan2
- SERPINA1 | c.267C>T p.S89= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as COSV63345627; called by muse, mutect2
- SH3YL1 | c.507G>A p.L169= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100642284; called by muse, mutect2, varscan2
- SIGLEC1 | c.870G>T p.L290= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99171545; called by muse, mutect2
- SIGLEC7 | c.1320C>T p.L440= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99978998; called by muse, mutect2, varscan2
- SIM1 | c.603C>T p.F201= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV53488902; called by muse, mutect2
- SLC27A1 | c.816C>T p.F272= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs781760092, COSV53095999; called by muse, mutect2, varscan2
- SMOX | c.1221G>A p.K407= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99603725; called by muse, mutect2, varscan2
- SMUG1 | c.243C>T p.F81= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99679593; called by muse, mutect2
- SOAT1 | c.1125G>A p.L375= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV100859127; called by muse, mutect2, varscan2
- SP110 | c.1788G>A p.E596= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as COSV99283929; called by muse, mutect2, varscan2
- SPRYD4 | c.501G>A p.V167= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100358527; called by muse, mutect2, varscan2
- STAB1 | c.2247G>C p.G749= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100402481; called by muse, mutect2, varscan2
- SULF2 | c.801C>A p.P267= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100737023, COSV100737532; called by muse, mutect2, varscan2
- SYF2 | c.549C>T p.V183= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV99360168; called by muse, mutect2, varscan2
- SYT10 | c.411C>T p.S137= | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as COSV57342905; called by muse, mutect2, varscan2
- SYT7 | c.321C>T p.L107= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs917455728, COSV55654193; called by muse, mutect2, varscan2
- TIMMDC1 | c.174C>T p.L58= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99809942; called by muse, mutect2, varscan2
- TLR3 | c.2352C>G p.L784= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV99711299; called by muse, mutect2, varscan2
- TRPS1 | c.3501G>C p.A1167= (on ENST00000220888 / NM_001330599.2; = p.A1180= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs764387571, COSV55227769, COSV55261126, COSV99635564; called by muse, mutect2, varscan2
- TRPV1 | c.2127G>C p.T709= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51517243, COSV99439917, COSV99441019; called by muse, mutect2, varscan2
- UBR4 | c.1683C>T p.S561= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs372095685; called by muse, mutect2, varscan2
- UBXN10 | c.333C>G p.L111= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100907877; called by muse, mutect2, varscan2
- USH1G | c.1362G>T p.P454= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100140681; called by muse, mutect2, varscan2
- USP9Y | c.3732G>A p.Q1244= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100168537; called by muse, mutect2, varscan2
- UTP15 | c.537C>G p.L179= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV57142075, COSV99707165; called by muse, mutect2, varscan2
- VPS13B | c.4647C>T p.V1549= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs753654004, COSV100661050, COSV100664098; called by muse, mutect2, varscan2
- XPO6 | c.735C>T p.I245= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100485482, COSV58965384; called by muse, mutect2, varscan2
- XPR1 | c.1221G>T p.L407= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV100851541; called by muse, mutect2, varscan2
- ZBED4 | c.1536G>A p.Q512= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV99351884; called by muse, mutect2, varscan2
- ZBED4 | c.1836G>A p.L612= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV99351886; called by muse, mutect2, varscan2
- ZCCHC9 | c.579G>A p.G193= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99562745; called by muse, mutect2, varscan2
- ZNF749 | c.108G>A p.V36= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV100494536; called by muse, mutect2, varscan2
- ZPBP2 | c.939G>A p.Q313= (on ENST00000348931 / NM_199321.3; = p.Q291= on NM_198844.3) | Silent (SNP) | VAF 19/272 reads (7%) | catalogued as COSV100818581; called by muse, mutect2
- C8orf86 | n.605A>T | RNA (SNP) | VAF 31/125 reads (25%) | catalogued as COSV100817609; called by muse, mutect2, varscan2
- CACNA1B | c.5223-1575dup | Intron (INS) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- DCAF13 | chr8:103415056 G>A | 5'Flank (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52566529; called by muse, mutect2, varscan2
- ELOB | c.*492C>T | 3'UTR (SNP) | VAF 24/132 reads (18%) | catalogued as COSV99241555, COSV99241806; called by muse, mutect2, varscan2
- FGFR3 | c.*1134C>G | 3'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53426313, COSV99603902; called by muse, mutect2, varscan2
- LRRC23 | c.*46C>G | 3'UTR (SNP) | VAF 25/148 reads (17%) | catalogued as COSV99145416; called by muse, mutect2, varscan2
- MIR521-1 | n.57G>C | RNA (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- PEX5L | c.-2G>A | 5'UTR (SNP) | VAF 28/237 reads (12%) | catalogued as COSV99830326; called by muse, mutect2, varscan2
- PMP2 | c.-2C>T | 5'UTR (SNP) | VAF 23/97 reads (24%) | catalogued as rs776446091, COSV56267605; called by muse, mutect2, varscan2
- POM121C | chr7:75416396 G>C | 3'Flank (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- SFRP1 | c.544+1877C>G | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99617961; called by muse, mutect2, varscan2
- SNORD116-6 | n.55G>A | RNA (SNP) | VAF 15/270 reads (6%) | called by muse, mutect2
- TTN | c.34264+2701C>A | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV60157484; called by muse, mutect2, varscan2
